Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5083, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5083-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE III/IV, 3.2 CM IN GREATEST DIMENSION.
- B. THE TUMOR HAS A PREDOMINANT GRANULAR (EOSINOPHILIC) MORPHOLOGY (See comment).
- C. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- D. NO INVASION OF THE RENAL VEIN, OR ITS BRANCHES, IS IDENTIFIED.
- E. NO EVIDENCE OF LYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. NON-NEOPLASTIC KIDNEY WITH NO SPECIFIC PATHOLOGIC ABNORMALITY.
- H. PATHOLOGIC STAGE: pTNM = pT1a NX MX.
- I. THE ADRENAL GLAND IS NOT SUBMITTED.

COMMENT:

The tumor has faintly granular eosinophilic cytoplasm and immunohistochemical stains are performed to rule out the possibility of chromophobe renal cell carcinoma. The neoplastic cells are positive for vimentin and CD10 and weakly positive for CK7. They are negative for Hale's colloidal iron. These findings are consistent with conventional (clear cell) renal cell carcinoma.

Source: NCI Genomic Data Commons file 5e64ed84-0038-4c60-b9d5-5e861554d831 (TCGA-B0-5083.41F37D91-3986-4EF4-A702-2BA44C6CBD48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).